Gene-level copy-number profile of tumor specimen HTMCP-01-01-00003-01D from CGCI case HTMCP-01-01-00003, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 33.2 years (12,136 days).
Specimen HTMCP-01-01-00003-01D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 20cbd67e-ccc3-4db9-9a06-e8b0f8870cce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-01-00003-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,753 have no estimate.
https://portal.gdc.cancer.gov/files/72ea4248-c9d1-440d-9efb-78aa1c90f8ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 818; copy number 1: 2,482; copy number 2: 52,260; copy number 3: 2,976; copy number 4: 168; copy number 5: 120; copy number 6: 31; copy number 8: 4; copy number 9: 1; copy number 10: 8; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): 306 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 40 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-30.
- chr2:89,959,979–90,070,238, 12 genes: IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.
- chr22:22,032,745–22,915,927, 126 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 166 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,766,540–143,797,108, 4 genes, copy number 5: FAM91A3P, AC239800.3, LINC02591, RNU1-143P.
- chr1:144,085,628–144,373,659, 8 genes, copy number 10: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr1:148,482,548–148,796,325, 8 genes, copy number 5: PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1.
- chr1:149,583,865–149,705,716, 6 genes, copy number 5 (within-gene range 3–5): PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P.
- chr1:243,005,845–243,101,744, 6 genes, copy number 5: AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P.
- chr4:49,229,573–49,489,554, 6 genes, copy number 5: AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3.
- chr8:7,200,756–7,200,857, 1 gene, copy number 5: AF228730.1.
- chr8:7,256,904–7,267,536, 2 genes, copy number 20: FAM90A15P, FAM90A3P.
- chr8:8,059,572–8,199,973, 3 genes, copy number 5–8 (within-gene range 3–8): AC105233.4, AC105233.2, MIR548I3.
- chr8:8,154,308–8,226,614, 3 genes, copy number 5: ENPP7P1, FAM85B, AC068020.1.
- chr9:39,816,542–40,106,661, 1 gene, copy number 5 (within-gene range 3–5): FGF7P3.
- chr9:39,886,861–40,806,344, 28 genes, copy number 5: RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1, CNN2P2, GXYLT1P3, AL591471.1, AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2, AL353626.3, RNU6-156P, AL353626.1.
- chr9:65,189,995–66,179,474, 27 genes, copy number 6 (within-gene range 4–6): BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr10:45,678,692–45,700,532, 1 gene, copy number 6: AGAP10P.
- chr14:18,333,726–18,650,966, 17 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr16:14,672,548–14,952,060, 20 genes, copy number 5: PLA2G10, AC009167.1, NPIPA3, AC136443.1, AC136443.4, NPIPA2, AC136443.2, ABCC6P2, NOMO1, AC136443.5, AC136443.3, MIR3179-1, MIR3670-1, AC138932.1, MIR3180-1, PKD1P3, Y_RNA, NPIPA1, MIR6511A1, MIR6770-1.
- chr16:29,483,642–29,505,999, 1 gene, copy number 6: NPIPB12.
- chr16:32,439,069–32,441,159, 1 gene, copy number 6: PABPC1P13.
- chr16:33,808,778–33,937,167, 8 genes, copy number 5–6: AC136428.3, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1.
- chr17:46,503,946–46,555,650, 3 genes, copy number 8–9: RDM1P2, LRRC37A2, RN7SL199P.
- chr22:15,282,557–15,578,006, 12 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1.

Autosomal genes at a single copy (total copy number 1): 138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
